Surgical pathology report (de-identified scan), TCGA case TCGA-AF-5654, project TCGA-READ (Rectum Adenocarcinoma), tissue source site Christiana Healthcare, specimen TCGA-AF-5654-01A (Primary Tumor).

[page 1 of 3]
PECIMEN

- A. Right ovary and fallopian tube
- B. Left ovary and tube
- C. Sigmoid colon upper rectum

CLINICAL NOTES

CLINICAL HISTORY: Rectal carcinoma.
PRE-OP DIAGNOSIS: Rectal cancer.

FROZEN SECTION DIAGNOSIS

fallopian tube: Benign, mature cystic teratoma.

GROSS DESCRIPTION

A. The specimen is received fresh for frozen section labeled "A. Right ovary and tube". It consists of a 470 gm., 13.0 x 12.0 x 7.0 cm. ovary with a very distorted fallopian tube measuring approximately 5 cm. in length and 0.2 cm. in diameter

with excessive adhesions. The ovarian surface has extensive adhesions but is otherwise tan to white without gross papillations. The specimen is sectioned to reveal a unilocular 0.2 cm. thick cyst filled with grumous tan to white material. There is some old calcification and some dark brown hair is present in the wall suggestive of a teratomatous cyst. Representative sections are froze as frozen sections AFS1 and AFS2. Additional sections are submitted for permanent sections with fallopian tube k 1 and sections of the ovarian cyst in 2 through 9. RS8.

B. Received fresh subsequently fixed in formalin labeled "left tube and ovary" is a 5 x 4.7 x 3.3 cm cystic ovary with an attached fimbriated fallopian tube. The specimen is opened and partially filled with clear fluid. The lining is smooth, glistening and shows no papillary excrescences present. Representative sections specimen are submitted in five cassettes. RS-5.

C. Received fresh, subsequently fixed in formalin labeled "sigmoid colon upper rectum". The specimen consist of a

24

cm. long portion of colon. The specimen is opened at both ends, proximal end is inked blue, distal end is inked black. The specimen

is partially covered with pink tan smooth glistening serosa with abundant yellow lobular fat. The specimen is opened to show pink tan smooth glistening mucosa with normal to abundant folds. The proximal circumference is 4.5 cm. and distal circumference is 10 cm.

Retroperitoneal reflection is located 3.5 cm. from the distal end. There is an exophytic tumor measuring 2.2 x 2.2 x 1.2 cm. located 3 cm. from the distal margin. The cut surface of the tumor shows no

[page 2 of 3]
[REDACTED]

discrete invasion into the muscularis propria. No other discrete gross lesions are identified. Lymph nodes are grossly identified in the fat. Representative sections of the specimen are submitted as follows: block 1 - representative luminal margins; block 2-5 - entire tumor to normal and fat; block 5 - representative margin; block 7-12 - possible lymph nodes. RS-12. [REDACTED].

[REDACTED]

MICROSCOPIC DESCRIPTION

A. Microscopic examination reveals an ovary with a benign mature cystic teratoma/dermoid cyst. No metastatic carcinoma is identified. The fallopian tube has a small serous paratubal cyst which is benign.

B. Microscopic examination of the left ovary and fallopian tube reveals a benign serous cystadenoma prominent tubo-ovarian adhesions and a benign fallopian tube with serous paratubal cyst.

C. Microscopic examination of the sigmoid colon and upper rectum resection reveals:

Histologic type: Adenocarcinoma.
Histologic grade: Moderately differentiated.
Primary tumor (pT): Tumor invades into muscularis propria in slides C3 and 4. No invasion beyond muscularis propria is identified (pT2).
Proximal margin: Negative for tumor.
Distal margin: Negative for tumor.
Circumferential (radial) margin: Negative for tumor.
Distance of tumor from closest margin: 3 cm from distal margin.
Vascular invasion: Not identified.
Regional lymph nodes (pN): Regional lymph nodes are all negative for metastatic tumor. (0/24) (pN0).
Non-lymph node pericolonic tumor: None identified.
Distant metastasis (pM): None identified (pMX).
Other findings: None.

4x2,14x1,15x1,5x1,3260F

DIAGNOSIS

A. Right ovary and fallopian tube, excision:
Mature cystic teratoma (dermoid cyst).

[page 3 of 3]
[REDACTED]

- Fallopian tube with benign serous paratubal cyst.
- B. Left ovary and fallopian tube, excision:
Benign serous cystadenoma.
Tubo-ovarian adhesions.
Benign serous paratubal cyst.
- C. Sigmoid colon and upper rectum, resection:
Invasive moderately-differentiated adenocarcinoma, invasive into
muscularis propria (pT2).
All resection margins are negative for tumor.
Twenty-four lymph nodes are negative for tumor (pN0).
See microscopic description.

[REDACTED]

[REDACTED]

--- End Of Report ---

Source: NCI Genomic Data Commons file 81e2e3b1-0dc4-4d08-9006-f4b86bb4d656 (TCGA-AF-5654.CAF5FC03-2B9B-4A80-8C60-EC43554DB280.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).